Somatic mutation profile of tumor specimen C3L-07012-54 (aliquot CPT0423540002) from CPTAC case C3L-07012, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 39.1 years (14,274 days).
Specimen C3L-07012-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4355d3e2-1b9c-4d66-ba7b-e8d331af9165.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07012-51 (Buccal Cell Normal), aliquot CPT0423600001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c70cb021-7dce-4c46-950e-339de5aff7d2

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 89/263 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 79/216 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, varscan2
- PTPN11 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 29/225 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121918453, CM013418, CM090463, COSV61004775, COSV61004869, COSV61006317; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- CDH24 | c.2413C>T p.R805C | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748718287; called by mutect2, varscan2
- FRMPD3 | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.484); catalogued as rs1194415691; called by muse, mutect2, varscan2
- WNT9B | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 80/154 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs375590479; called by muse, mutect2, varscan2
- ADCY2 | c.1817G>T p.C606F | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPM1 | c.847-4_860delinsTCCAGGCTCTTCAAGATCTCTGC p.X283_splice | Splice Site (INS) | VAF 13/83 reads (16%) | called by pindel, varscan2*
- OR52J3 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- POM121L2 | c.2623G>A p.G875R | Missense Mutation (SNP) | VAF 102/246 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- RNASE9 | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLK | c.540C>T p.N180= | Silent (SNP) | VAF 9/129 reads (7%) | catalogued as rs773447309; called by muse, mutect2
- ZNF99 | c.1611C>T p.Y537= | Silent (SNP) | VAF 12/291 reads (4%) | catalogued as rs1458247128; called by muse, mutect2
- PIN4 | c.119-73C>T | Intron (SNP) | VAF 89/290 reads (31%) | catalogued as rs749259442; called by muse, mutect2, varscan2
